Gene-level copy-number profile of tumor specimen TCGA-VS-A94Y-01A from TCGA case TCGA-VS-A94Y, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 47.8 years (17,465 days).
Specimen TCGA-VS-A94Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.1a36ceb6-8a9f-4f43-b923-9dfba950bdad.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VS-A94Y-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2c6218ea-20de-4f60-86bc-59e5a95dbe0a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 60; copy number 2: 16,059; copy number 3: 8,566; copy number 4: 27,927; copy number 5: 138; copy number 6: 6,501; copy number 7: 100; copy number 8: 135; copy number 9: 99; copy number 10: 121; copy number 11: 54; copy number 13: 45.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VS-A94Y-01A-11D-A386-01): tumor purity 0.72, ploidy 1.84, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,992,543–141,208,376, 3 genes: Y_RNA, RNU6-904P, RPS16P3.
- chr3:95,654,423–95,919,552, 2 genes: MTHFD2P1, AC106719.1.
- chr4:86,336,318–86,336,614, 1 gene: RN7SKP96.
- chr9:9,799,423–9,803,784, 1 gene: AL513422.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 319 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:175,877,343–178,484,147, 29 genes, copy number 11 (within-gene range 2–13): LINC01657, LINC02803, RPS29P5, COP1, SCARNA3, AL590723.1, AL591043.2, U7, AL359265.2, RNU2-12P, AL359265.1, AL591043.1, MORF4L1P7, PAPPA2, PTP4A1P7, AL031290.1, ASTN1, MIR488, BRINP2, LINC01645, AL136114.1, LINC01741, SEC16B, CRYZL2P-SEC16B, CRYZL2P, AL359075.1, RASAL2-AS1, RASAL2, AL160281.1.
- chr2:19,910,263–20,651,130, 24 genes, copy number 9 (within-gene range 6–9): WDR35, AC079145.1, MATN3, LAPTM4A, LAPTM4A-DT, AC098828.1, RPS16P2, RN7SL140P, RNU6-961P, SDC1, DRG1P1, RNU7-113P, PUM2, SLC7A15P, RNA5SP86, RHOB, AC023137.1, Y_RNA, AC012065.1, NDUFAF2P1, HS1BP3, AC012065.2, HS1BP3-IT1, RPS25P3.
- chr3:188,947,214–189,325,304, 1 gene, copy number 11 (within-gene range 6–11): TPRG1.
- chr3:189,238,686–189,240,594, 1 gene, copy number 11: TPRG1-AS2.
- chr6:47,231,532–49,078,051, 22 genes, copy number 9: TNFRSF21, B3GNTL1P2, AL451166.1, AL355353.1, CD2AP, Y_RNA, AL358178.1, ADGRF2, ADGRF4, RN7SKP116, AL356421.2, AL356421.1, OPN5, RNU1-105P, PTCHD4, AL353138.1, HNRNPA3P4, RBMXP1, FO393412.1, AL391538.1, AL022099.1, AL589994.1.
- chr8:41,261,962–41,896,762, 23 genes, copy number 11 (within-gene range 6–11): SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P.
- chr12:66,023,620–67,590,771, 28 genes, copy number 9 (within-gene range 6–9): MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB, GRIP1, OSBPL9P5, OSBPL9P4, AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, AC078983.1, MRPL40P1, NTAN1P3, LINC02420, LINC02408.
- chr12:68,332,888–68,451,663, 1 gene, copy number 9 (within-gene range 6–9): LINC02384.
- chr12:68,426,331–69,224,242, 24 genes, copy number 9: AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1.
- chr22:18,906,028–21,471,269, 154 genes, copy number 10–13 (broad region; genes not listed).
- chr22:33,162,226–33,922,841, 1 gene, copy number 10 (within-gene range 6–10): LARGE1.
- chr22:33,320,865–33,436,669, 2 genes, copy number 10: Z82173.1, MIR4764.
- chr22:43,528,744–44,010,531, 9 genes, copy number 10 (within-gene range 2–10): EFCAB6, Z97055.1, HMGN2P9, Z97055.2, SULT4A1, PNPLA5, PNPLA3, SAMM50, RPL35AP36.

Autosomal genes at a single copy (total copy number 1): 60. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
